Gene-level copy-number profile of tumor specimen TCGA-EE-A2GI-06A from TCGA case TCGA-EE-A2GI, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 41.2 years (15,065 days).
Specimen TCGA-EE-A2GI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.2d3e7480-bb4b-481e-ac68-964d7dcda5d8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2GI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccf6ae59-ef5f-4fc1-af6b-38fe3eac4ae5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,080; copy number 2: 2,953; copy number 3: 8,275; copy number 4: 24,730; copy number 5: 7,215; copy number 6: 11,365; copy number 7: 110; copy number 8: 2,239; copy number 9: 258; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2GI-06A-11D-A194-01): tumor purity 0.54, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 259 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:184,999,710–186,681,446, 39 genes, copy number 9: LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR.
- chr1:214,603,195–218,541,899, 34 genes, copy number 9: CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3.
- chr4:10,238,213–27,282,225, 184 genes, copy number 9 (broad region; genes not listed).
- chr7:78,347,142–78,359,458, 1 gene, copy number 9: RPL13AP17.
- chr19:22,243,254–22,245,347, 1 gene, copy number 11: AC073539.1.

Autosomal genes at a single copy (total copy number 1): 700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
